CCDI case PBCIPG — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Bones, joints and articular cartilage of other and unspecified sites.
https://portal.gdc.cancer.gov/cases/97ccb51c-7888-41be-a769-a65918bb8d47

Demographics
Sex at birth: female; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8900/3; Tissue or organ of origin: Pelvis, NOS; Age at diagnosis: 9.1 years (3,338 days).

Biospecimens (3 samples)
- Samples 0DSR4U, 0DSR56 (2 with the same recorded description): Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DSR5B: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
